Surgical pathology report (de-identified scan), TCGA case TCGA-IE-A3OV, project TCGA-SARC (Sarcoma), tissue source site ABS - IUPUI, specimen TCGA-IE-A3OV-01A (Primary Tumor).

[page 1 of 2]
1CD-0-3

leiomyosarcoma, NOS 8890/3

Site: thigh, NOS C 49.2

hw
2/5/12

NEW DOCUMENT:

Operative Procedure:

Wide resection of left thigh sarcoma.

Specimen Received:

- A: Anterior margin (FS)
- B: Skin, distal margin (FS)
- C: Skin, posterior margin (FS)
- D: Skin, proximal margin (FS)
- E: Skin, deep margin (FS)
- F: Left thigh mass

Final Pathologic Diagnosis:

- A. Soft tissue, anterior margin:
Negative for malignancy, frozen section diagnosis confirmed.
- B. Skin, distal margin:
Negative for malignancy, frozen section diagnosis confirmed.
- C. Skin, posterior margin:
Negative for malignancy, frozen section diagnosis confirmed.
- D. Skin, proximal margin:
Negative for malignancy, frozen section diagnosis confirmed.
- E. Skin, deep margin:
Negative for malignancy, frozen section diagnosis confirmed.
- F. Soft tissue, left thigh, mass excision:
Tumor histologic type: Leiomyosarcoma.
Size: 10.5 cm in greatest dimension.
Grade: High grade.
Resection margins: Negative for malignancy.

pT2b, NX, MX

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Note:

This is a highly pleomorphic spindle cell sarcoma with a prominent fascicular pattern. Mitotic activity is brisk (>15/10hpf) and necrosis is widespread. The tumor cells are reactive for vimentin, small muscle actin, and desmin. They are immunonegative for S100 and pancytokeratin. These features are consistent with

[page 2 of 2]
having overall dimensions of 10.5 x 4.8 x 5.0 cm. The cut surface is pale pink and fleshy with a fibrous appearance. There is myxoid foci present.

Percent necrosis (< or > 15%): There is less than 1% necrosis.

Closest resection margins and distance: The closest resection margin is 0.2 cm.

Other findings: There is a centrally coursing arteriovenous complex, which is grossly involved by the aforementioned mass.

Blocks submitted:

F1 closest resection margin;

F2 central coursing vascular complex to include involvement by mass;

F3-8 representative sections of mass.

Microscopic Description:

Vimentin, SMA, desmin, pan cytokeratin, and S-100 special stains pending.

Taken:

DOB:

(Age:

Gender:

Source: NCI Genomic Data Commons file 4a316697-b815-485e-991d-3394f2609d1b (TCGA-IE-A3OV.691C38E1-979E-44CE-BDA0-ABA51FEB98C4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).